Gene-level copy-number profile of tumor specimen TCGA-12-0826-01A from TCGA case TCGA-12-0826, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 38.0 years (13,887 days).
Specimen TCGA-12-0826-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.c29ad7ad-4b25-4a4c-bb65-0b4eeb502e50.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-0826-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6747cb94-d122-4ea5-9947-49f99d3b7b40

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,489; copy number 3: 4,655; copy number 4: 11,924; copy number 5: 13,737; copy number 6: 22,022; copy number 7: 1,851; copy number 12: 3,014; copy number 18: 21; copy number 22: 10; copy number 28: 1; copy number 61: 1; copy number 63: 1; copy number 66: 3; copy number 70: 5; copy number 77: 3; copy number 83: 65; copy number 104: 1; copy number 106: 15; copy number 117: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-0826-01A-01D-0384-01): tumor purity 0.49, ploidy 4.71, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 127 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:1,500,525–1,788,674, 6 genes, copy number 22–77 (within-gene range 6–77): LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1.
- chr12:6,970,913–7,218,574, 15 genes, copy number 106 (within-gene range 6–106): EMG1, LPCAT3, C1S, AC006512.1, AC006512.2, C1R, C1RL, C1RL-AS1, RBP5, RNU6-485P, AC018653.3, CLSTN3, AC018653.4, AC018653.1, PEX5.
- chr12:20,361,732–20,370,262, 1 gene, copy number 28: AC129102.1.
- chr12:41,764,144–41,774,671, 1 gene, copy number 117: LINC02400.
- chr12:57,591,174–57,808,071, 21 genes, copy number 18 (within-gene range 5–18): PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM.
- chr12:67,989,445–68,234,686, 1 gene, copy number 83 (within-gene range 5–83): IFNG-AS1.
- chr12:68,143,318–70,637,440, 63 genes, copy number 83 (broad region; genes not listed).
- chr12:70,671,918–70,672,856, 1 gene, copy number 83: FAHD2P1.
- chr12:71,582,293–71,594,404, 2 genes, copy number 66: AC078860.3, AC078860.2.
- chr12:76,137,425–76,348,415, 5 genes, copy number 70: AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10.
- chr12:98,931,682–98,976,656, 1 gene, copy number 66 (within-gene range 5–66): AC069437.1.
- chr12:105,107,324–105,169,130, 1 gene, copy number 104 (within-gene range 6–104): WASHC4.
- chr12:115,263,170–115,300,708, 2 genes, copy number 61–63: AC078880.1, AC078880.3.
- chr12:120,687,149–120,723,640, 7 genes, copy number 22: MLEC, AC069234.2, AC069234.5, AC069234.4, UNC119B, AC069234.3, MIR4700.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
